Gene-level copy-number profile of tumor specimen TCGA-VR-AA7D-01A from TCGA case TCGA-VR-AA7D, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 58.8 years (21,468 days).
Specimen TCGA-VR-AA7D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.aea93b41-2aaa-4f8c-837e-c7df435d97eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-AA7D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85d3f9ba-f686-42b2-8515-ff1f5765816d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 9,485; copy number 2: 40,142; copy number 3: 5,094; copy number 4: 3,785; copy number 5: 1,236; copy number 11: 20; copy number 17: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-AA7D-01A-11D-A402-01): tumor purity 0.7, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–22,128,103, 6 genes (within-gene range 0–3): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,307 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:187,796,187–191,330,536, 37 genes, copy number 5 (within-gene range 4–5): AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B.
- chr8:73,008,856–133,963,259, 887 genes, copy number 5 (broad region; genes not listed).
- chr8:134,211,865–134,320,447, 1 gene, copy number 5 (within-gene range 4–5): AC105180.1.
- chr8:135,742,343–139,127,953, 16 genes, copy number 5: RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2.
- chr9:77,423,079–82,780,194, 56 genes, copy number 5: GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P, GNAQ, AL353705.2, RN7SKP59, ASS1P3, AL353705.1, AL353705.3, CEP78, PSAT1, AL592221.1, MTND2P8, KRT18P24, AL512634.1, CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507, NPAP1P4, MTCO1P51, MTND2P9, RPS19P6, AL138749.1, RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12.
- chr9:100,099,243–100,302,175, 1 gene, copy number 5 (within-gene range 4–5): INVS.
- chr9:100,175,178–113,682,855, 212 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:114,572,901–116,402,321, 23 genes, copy number 5: AL160275.2, ATP6V1G1, TMEM268, Y_RNA, TEX53, TEX48, AL160275.1, AL390240.1, TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1.
- chr9:116,504,283–116,701,300, 3 genes, copy number 5: ASTN2-AS1, AL133284.1, TRIM32.
- chr11:68,612,899–71,524,107, 71 genes, copy number 11–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
